Somatic mutation profile of tumor specimen TCGA-4Z-AA87-01A (aliquot TCGA-4Z-AA87-01A-11D-A391-08) from TCGA case TCGA-4Z-AA87, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 72.4 years (26,430 days).
Specimen TCGA-4Z-AA87-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bec6fe9-a722-4455-9660-43dad60ad6d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4Z-AA87-10A (Blood Derived Normal), aliquot TCGA-4Z-AA87-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/285c9f63-5ae2-4bc0-8ff0-3530ce77632a

The open-access MAF lists 268 somatic variants for this specimen: 198 protein-altering or splice-affecting, 63 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 172, Silent 63, Nonsense Mutation 15, Frame Shift Del 5, Splice Site 4, Intron 3, RNA 2, 3'Flank 1, Splice Region 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.97-1G>A p.X33_splice | Splice Site (SNP) | VAF 109/152 reads (72%) | hotspot (GDC flag); catalogued as CS971912, COSV52665806, COSV52762622, COSV52838014; called by muse, mutect2, varscan2
- ACACB | c.152C>G p.S51C | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV58146179; called by muse, mutect2, varscan2
- ACAD9 | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58309895; called by muse, varscan2
- ADAMTS12 | c.1507G>T p.V503L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV61262006; called by muse, mutect2, varscan2
- ADD1 | c.674C>G p.S225C | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780341390, COSV53274189; called by muse, mutect2, varscan2
- ADGRL3 | c.2077C>T p.Q693* (on ENST00000506720 / NM_001322402.2; = p.Q625* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 61/106 reads (58%) | catalogued as COSV101547354; called by muse, mutect2, varscan2
- AFF1 | c.2880C>T p.D960= | Splice Region (SNP) | VAF 32/130 reads (25%) | catalogued as rs1298994484, COSV57123881; called by muse, varscan2
- AKAP9 | c.10008G>A p.M3336I (on ENST00000359028; = p.M3312I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.116); catalogued as COSV62357529; called by muse, mutect2, varscan2
- ALMS1 | c.4513G>A p.A1505T | Missense Mutation (SNP) | VAF 104/147 reads (71%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as COSV52521635; called by muse, mutect2, varscan2
- ANKEF1 | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.178); catalogued as rs776774392, COSV65693635; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2845C>T p.L949F | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV51857920; called by muse, mutect2, varscan2
- AQP5 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1328341018, COSV52231375, COSV52231941; called by muse, mutect2, varscan2
- ARHGEF3 | c.266G>C p.R89T | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV56332354; called by muse, mutect2, varscan2
- ATN1 | c.2352C>A p.F784L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1418627045, COSV100755921, COSV63112947; called by muse, mutect2, varscan2
- ATP1A4 | c.495C>G p.I165M | Missense Mutation (SNP) | VAF 87/152 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63626018, COSV63628465, COSV63628816; called by muse, mutect2, varscan2
- AVPR1A | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1321994497, COSV54548021; called by mutect2, varscan2
- AZIN2 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756639325, COSV53857365; called by muse, mutect2, varscan2
- BAP1 | c.269C>G p.S90C | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56240051, COSV99963657; called by muse, mutect2, varscan2
- BBS9 | c.2290C>A p.Q764K (on ENST00000242067 / NM_001348036.1; = p.Q724K on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV54186547; called by muse, mutect2, varscan2
- BCL11B | c.744C>G p.I248M (on ENST00000357195 / NM_001282237.2; = p.I177M on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61739194; called by muse, varscan2
- BORA | c.1753G>A p.D585N (on ENST00000613797; = p.D510N on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV64697224; called by muse, mutect2, varscan2
- BPNT2 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324153760, COSV52909002; called by muse, mutect2, varscan2
- BTN3A1 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as COSV50025375; called by muse, mutect2, varscan2
- C4orf45 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV71701358; called by muse, mutect2, varscan2
- CATSPER4 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs534133361, COSV58794308, COSV58794663; called by muse, mutect2, varscan2
- CATSPERB | c.594C>G p.F198L | Missense Mutation (SNP) | VAF 99/118 reads (84%) | SIFT tolerated (0.82); PolyPhen benign (0.028); catalogued as COSV56434885; called by muse, mutect2, varscan2
- CENPI | c.2218C>T p.H740Y | Missense Mutation (SNP) | VAF 45/60 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as rs757961032, COSV54506187; called by muse, mutect2, varscan2
- CHD4 | c.1234G>C p.E412Q (on ENST00000357008 / NM_001363606.2; = p.E425Q on NM_001273.5) | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV58910475; called by muse, mutect2, varscan2
- CNTN4 | c.3068G>C p.R1023T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV61880807; called by muse, mutect2, varscan2
- COL4A6 | c.3809G>A p.R1270Q | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.64); PolyPhen benign (0.153); catalogued as rs771134556, COSV57877487; called by muse, mutect2, varscan2
- CPNE7 | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs767725210, COSV52016440; called by muse, mutect2, varscan2
- CR2 | c.1405G>T p.A469S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as COSV65509566; called by muse, mutect2, varscan2
- CRIM1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.622); catalogued as COSV54872318; called by muse, mutect2, varscan2
- CRYZ | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV61718589; called by muse, mutect2, varscan2
- CSMD1 | c.10333G>C p.E3445Q (on ENST00000520002; = p.E3444Q on NM_033225.6) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.188); catalogued as COSV59282113, COSV59380793; called by muse, mutect2, varscan2
- DCLK1 | c.1766+1G>C p.X589_splice | Splice Site (SNP) | VAF 5/29 reads (17%) | catalogued as COSV55210320; called by muse, mutect2, varscan2
- DNA2 | c.1878G>C p.L626F | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64430170; called by muse, mutect2, varscan2
- DPEP3 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1007175149, COSV99262850; called by muse, mutect2, varscan2
- DTNBP1 | c.890C>G p.S297C | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV59043819; called by muse, mutect2, varscan2
- EDRF1 | c.2402A>T p.D801V (on ENST00000356792 / NM_001202438.2; = p.D767V on NM_015608.2) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1426211069, COSV61766179; called by muse, mutect2, varscan2
- ERAP1 | c.1300G>C p.D434H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57091315; called by muse, mutect2, varscan2
- ERCC2 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV55544528; called by muse, mutect2, varscan2
- FAM120B | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs754445368, COSV53006914; called by muse, mutect2, varscan2
- FAM133B | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1383580765, COSV101300226; called by muse, mutect2, varscan2
- FAM83D | c.1327C>T p.Q443* | Nonsense Mutation (SNP) | VAF 22/77 reads (29%) | catalogued as COSV54156355, COSV54158010, COSV99465009; called by muse, mutect2, varscan2
- FCGBP | c.9575C>T p.A3192V | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs754308006; called by muse, mutect2
- FGF8 | c.480G>C p.Q160H (on ENST00000344255 / NM_033164.4; = p.Q142H on NM_006119.6) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1306822945, COSV60142688, COSV60143440; called by muse, mutect2, varscan2
- FTMT | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58419681; called by muse, mutect2, varscan2
- GH2 | c.395C>G p.S132W | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60427809; called by muse, mutect2, varscan2
- GLDC | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 122/281 reads (43%) | catalogued as COSV100394485; called by muse, mutect2, varscan2
- GMCL1 | c.273G>C p.K91N | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs374656847; called by muse, varscan2
- GRIP1 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370700342; called by muse, mutect2, varscan2
- GUCY1A1 | c.957T>G p.N319K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56656377; called by muse, mutect2, varscan2
- HBS1L | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 7/89 reads (8%) | catalogued as COSV100892665; called by muse, mutect2
- HEATR1 | c.4225G>A p.E1409K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV63982971; called by muse, mutect2, varscan2
- HEG1 | c.383A>T p.Q128L | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as COSV60765458; called by muse, mutect2, varscan2
- HNRNPLL | c.1574-1G>C p.X525_splice | Splice Site (SNP) | VAF 18/80 reads (23%) | catalogued as COSV55367931; called by muse, varscan2
- HNRNPUL2 | c.1231G>C p.E411Q | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV57133776; called by muse, mutect2, varscan2
- HOXC6 | c.152C>G p.S51W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54537569; called by muse, mutect2, varscan2
- IGSF5 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.828); catalogued as rs1241036743, COSV66029191; called by muse, mutect2, varscan2
- IL17RE | c.1910G>A p.W637* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as rs1169037007, COSV99925220; called by muse, mutect2, varscan2
- IRX4 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1453473481, COSV51473443; called by muse, mutect2, varscan2
- ITGB6 | c.981C>G p.I327M | Missense Mutation (SNP) | VAF 100/205 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51798479; called by muse, mutect2, varscan2
- KIF21B | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59766068; called by muse, mutect2, varscan2
- KLF5 | c.295C>G p.Q99E | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.185); catalogued as rs375892924; called by muse, mutect2, varscan2
- KLHL41 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.099); catalogued as COSV52931678; called by muse, mutect2, varscan2
- KMT2E | c.4274C>T p.S1425F | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV57579487; called by muse, mutect2, varscan2
- KRTAP10-10 | c.169T>C p.C57R | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV59979265; called by muse, mutect2, varscan2
- KRTAP13-4 | c.479G>A p.C160Y | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV61880286; called by muse, mutect2, varscan2
- KRTAP4-12 | c.315C>G p.C105W | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67458277; called by muse, varscan2
- LPA | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as rs777971266, COSV60311607; called by muse, mutect2, varscan2
- LRGUK | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.012); catalogued as COSV53642109, COSV53643146; called by muse, mutect2, varscan2
- LRP2 | c.11794G>A p.E3932K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55560206; called by muse, mutect2, varscan2
- LRRC37B | c.1981C>T p.L661F | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV58954838; called by muse, mutect2, varscan2
- LRRN1 | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs773309234, COSV60014720; called by muse, mutect2, varscan2
- LYG1 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV57916097; called by muse, mutect2, varscan2
- MACF1 | c.8779C>G p.H2927D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV57143185; called by muse, mutect2, varscan2
- MAGI3 | c.2290G>C p.D764H | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56843932; called by muse, mutect2, varscan2
- MAPK4 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); catalogued as rs779386468, COSV68543752; called by muse, mutect2, varscan2
- MCEE | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 228/288 reads (79%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1376776866, COSV54905796, COSV54907157; called by muse, varscan2
- MEIS2 | c.85G>A p.A29T (on ENST00000561208 / NM_170675.5; = p.A16T on NM_002399.3) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.732); catalogued as COSV54942744; called by muse, mutect2, varscan2
- MESD | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55726465; called by muse, mutect2, varscan2
- MTIF2 | c.1898C>G p.S633C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.269); catalogued as rs1221195792, COSV55054099; called by muse, mutect2, varscan2
- MUC16 | c.34445C>A p.P11482Q | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); catalogued as COSV67492064; called by muse, mutect2, varscan2
- MUC7 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.855); catalogued as COSV59220096; called by muse, mutect2, varscan2
- MYO1F | c.1443G>C p.Q481H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV57800076; called by muse, mutect2, varscan2
- MYOM3 | c.3668C>G p.S1223C | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV58400629; called by muse, mutect2, varscan2
- NCKAP5 | c.3280G>A p.D1094N | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV58462816, COSV58474131; called by muse, mutect2, varscan2
- NKAIN2 | c.573A>C p.Q191H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); catalogued as COSV63730598; called by muse, mutect2, varscan2
- NKX2-2 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs1180786196, COSV65819325; called by muse, mutect2
- NLRP5 | c.2870G>C p.C957S | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0.222); catalogued as COSV66767225; called by muse, varscan2
- NR1H3 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV68008863; called by muse, mutect2, varscan2
- NRG3 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.629); catalogued as rs763979395, COSV64569234, COSV64583299; called by muse, mutect2, varscan2
- NUDT22 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV54175764; called by muse, mutect2, varscan2
- ODF3L2 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368425489, COSV52749355; called by muse, mutect2, varscan2
- OR5T3 | c.148A>C p.T50P | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57382521; called by muse, mutect2
- OR8B4 | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV62070052, COSV62070546; called by muse, mutect2, varscan2
- PALLD | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); catalogued as rs1255873290, COSV54994377; called by muse, mutect2, varscan2
- PAN2 | c.3553G>A p.E1185K (on ENST00000425394 / NM_001127460.3; = p.E1181K on NM_014871.5) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV56263857; called by muse, mutect2, varscan2
- PCDHB4 | c.120C>A p.S40R | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.079); catalogued as COSV52021771, COSV52026855; called by muse, mutect2, varscan2
- PCLO | c.15326A>G p.K5109R | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61664786; called by muse, mutect2, varscan2
- PCLO | c.12606A>C p.K4202N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV61629441; called by muse, mutect2, varscan2
- PDIA3 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV55858262; called by muse, mutect2, varscan2
- PDSS1 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 30/508 reads (6%) | catalogued as rs749092951, COSV100873614; called by muse, mutect2
- PGAP1 | c.836C>G p.S279* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100698340; called by muse, mutect2, varscan2
- PGAP6 | c.2060C>T p.S687L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as rs530798560, COSV51737928; called by muse, mutect2, varscan2
- PGGHG | c.2103C>A p.F701L | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV66887832, COSV66888625; called by muse, mutect2, varscan2
- PHF2 | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100823299; called by muse, mutect2
- PIK3CA | c.1906G>C p.V636L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99842286; called by muse, mutect2
- PLEKHA7 | c.2405T>C p.F802S | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs749209716, COSV63043367; called by muse, mutect2, varscan2
- PLEKHG7 | c.1732G>C p.D578H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774991604, COSV60822757; called by muse, mutect2, varscan2
- PLXNA1 | c.4317G>T p.K1439N | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV52532368; called by muse, mutect2, varscan2
- POLA2 | c.350C>G p.S117* | Nonsense Mutation (SNP) | VAF 35/106 reads (33%) | catalogued as COSV99641264; called by muse, mutect2, varscan2
- PPP1R16B | c.433G>C p.G145R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV55384477; called by mutect2, varscan2
- PPP1R3A | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV52892743, COSV99492439; called by muse, mutect2, varscan2
- PREX1 | c.1864C>G p.L622V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs774681439, COSV64256651; called by muse, mutect2, varscan2
- PURB | c.782C>G p.P261R | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67480598; called by muse, mutect2, varscan2
- RAG1 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.235); catalogued as rs1232282131, COSV55028044; called by muse, mutect2, varscan2
- RBIS | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.07); catalogued as COSV56275814, COSV99809688; called by muse, mutect2, varscan2
- RBP4 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65160781; called by muse, mutect2, varscan2
- REPIN1 | c.735C>A p.F245L | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs748530989, COSV68292968; called by muse, mutect2, varscan2
- RFC1 | c.2317C>G p.Q773E (on ENST00000381897 / NM_001363496.2; = p.Q772E on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV62901063; called by muse, varscan2
- RFC1 | c.2269C>T p.H757Y (on ENST00000381897 / NM_001363496.2; = p.H756Y on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62901067; called by muse, varscan2
- RGS22 | c.290T>C p.M97T | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.026); catalogued as COSV62667383; called by muse, mutect2
- RHBDD1 | c.237G>T p.W79C | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58131450, COSV58132011; called by muse, mutect2, varscan2
- RHOB | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV55355253; called by muse, mutect2, varscan2
- RP1L1 | c.4176G>T p.E1392D | Missense Mutation (SNP) | VAF 88/299 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as COSV66760030; called by muse, mutect2, varscan2
- RPL8 | c.668C>A p.S223Y | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52800118; called by muse, mutect2, varscan2
- RXRB | c.1336C>G p.L446V | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59502319; called by muse, mutect2, varscan2
- RYR2 | c.4297T>C p.F1433L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.6); catalogued as COSV63712487; called by muse, mutect2, varscan2
- SCAPER | c.334C>G p.R112G | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57753767; called by muse, mutect2, varscan2
- SGO1 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 143/229 reads (62%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs761667197, COSV55425222; called by muse, mutect2, varscan2
- SGPL1 | c.1128C>A p.F376L | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV64592498; called by muse, mutect2, varscan2
- SH3D19 | c.1073C>G p.S358C | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV58793926; called by muse, mutect2, varscan2
- SH3PXD2A | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1414110348, COSV60120562; called by muse, mutect2, varscan2
- SHPRH | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as rs755201463, COSV99262586; called by muse, mutect2, varscan2
- SIRPB1 | c.243G>C p.Q81H | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV53540696; called by muse, mutect2, varscan2
- SIRT7 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV58711822; called by muse, varscan2
- SLC19A2 | c.1475C>G p.S492C | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); catalogued as COSV104376896, COSV52548996; called by muse, mutect2, varscan2
- SLC28A2 | c.1514A>T p.K505I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV61665227; called by muse, mutect2, varscan2
- SLFN13 | c.2026G>T p.E676* | Nonsense Mutation (SNP) | VAF 47/144 reads (33%) | catalogued as COSV99540283; called by muse, varscan2
- SLFN13 | c.1996G>T p.V666F | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV53195567; called by muse, varscan2
- SMARCC2 | c.1588C>G p.H530D | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57224746; called by muse, mutect2, varscan2
- SMG1 | c.7610C>T p.S2537F | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV67174750; called by muse, mutect2, varscan2
- SNRPA | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV54681420; called by muse, mutect2
- SPTAN1 | c.1843C>T p.Q615* | Nonsense Mutation (SNP) | VAF 26/31 reads (84%) | catalogued as COSV100823930; called by muse, mutect2, varscan2
- ST6GAL1 | c.766G>T p.V256L | Missense Mutation (SNP) | VAF 46/200 reads (23%) | PolyPhen benign (0.068); catalogued as COSV51474962; called by muse, mutect2, varscan2
- STAT5B | c.1185G>C p.E395D | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV53181838, COSV53185819; called by muse, mutect2, varscan2
- STBD1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs371699339; called by muse, mutect2, varscan2
- STK10 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs757807481, COSV51575397; called by muse, mutect2, varscan2
- STXBP5L | c.2423A>C p.N808T | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV56534134; called by muse, mutect2, varscan2
- SWT1 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV62258951; called by muse, mutect2, varscan2
- SYDE1 | c.2176G>C p.E726Q | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54622405; called by muse, mutect2, varscan2
- SYT16 | c.889A>G p.R297G | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1171744559, COSV70859796; called by muse, mutect2
- TAF1 | c.4467C>A p.F1489L (on ENST00000373790 / NM_138923.4; = p.F1510L on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/55 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV52124630; called by muse, varscan2
- TBL1X | c.123C>G p.I41M | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV54288299; called by muse, mutect2, varscan2
- TECRL | c.287-1G>T p.X96_splice | Splice Site (SNP) | VAF 19/80 reads (24%) | catalogued as COSV67090505; called by muse, mutect2, varscan2
- TEX15 | c.4390G>C p.V1464L (on ENST00000256246; = p.V1847L on NM_001350162.2) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV56353409; called by muse, mutect2, varscan2
- TFRC | c.2131G>A p.A711T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1011217415, COSV64056429; called by muse, mutect2, varscan2
- THBS1 | c.1825G>C p.E609Q | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as COSV52955714; called by muse, mutect2, varscan2
- TLR3 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57170374; called by muse, mutect2, varscan2
- TMF1 | c.1402C>G p.L468V | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1239792695, COSV68375873; called by muse, mutect2, varscan2
- TMTC1 | c.1250G>C p.S417T (on ENST00000539277 / NM_001193451.2; = p.S309T on NM_175861.3) | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs971478228, COSV55493229; called by muse, mutect2, varscan2
- TNRC6A | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100170394; called by muse, mutect2, varscan2
- TRIM13 | c.43A>G p.S15G | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.04); catalogued as COSV53951573; called by muse, mutect2, varscan2
- TRPM3 | c.2516G>A p.R839Q (on ENST00000357533 / NM_001366142.2; = p.R682Q on NM_020952.6) | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.069); catalogued as rs769024160, COSV62583644; called by muse, mutect2, varscan2
- TST | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs147975715, COSV50765813; called by mutect2, varscan2
- TTLL13P | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 54/326 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60040026; called by muse, mutect2, varscan2
- TXNDC16 | c.2405G>C p.R802T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as COSV55987392; called by muse, mutect2, varscan2
- UBR2 | c.4234G>A p.D1412N | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1352311090, COSV65752476; called by muse, mutect2, varscan2
- UBR5 | c.523C>G p.Q175E | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.585); catalogued as COSV55291725; called by muse, mutect2, varscan2
- USP10 | c.811C>G p.Q271E | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.036); catalogued as COSV54752841; called by muse, mutect2, varscan2
- USP11 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1003392081, COSV52093861; called by muse, mutect2, varscan2
- USP34 | c.7124G>A p.R2375H | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs1008915384, COSV68406315; called by muse, mutect2, varscan2
- USP36 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs746734943, COSV100361742, COSV61754261; called by muse, mutect2, varscan2
- USP47 | c.1062G>C p.E354D (on ENST00000399455 / NM_001372095.1; = p.E266D on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100360029, COSV60467888; called by mutect2, varscan2
- WDR6 | c.2467A>G p.S823G | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV58247402; called by muse, mutect2, varscan2
- XKR7 | c.1684C>T p.Q562* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as COSV101629294; called by muse, mutect2, varscan2
- XPR1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62560458; called by muse, mutect2, varscan2
- XRCC4 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as rs774555675, COSV56545395, COSV99983323; called by muse, mutect2, varscan2
- ZC3H3 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs776857943, COSV99368410; called by muse, varscan2
- ZC3HAV1 | c.1064C>G p.S355* | Nonsense Mutation (SNP) | VAF 37/139 reads (27%) | catalogued as COSV99648982; called by muse, mutect2, varscan2
- ZNF236 | c.2783C>G p.S928C | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV53497411; called by muse, mutect2, varscan2
- ZNF417 | c.120C>G p.Y40* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | catalogued as COSV100364374; called by muse, mutect2, varscan2
- ZNF426 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as rs942375033, COSV53468832; called by muse, mutect2, varscan2
- ZNF44 | c.1225C>G p.L409V (on ENST00000356109 / NM_001164276.2; = p.L361V on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as rs760810887, COSV61136288; called by muse, mutect2, varscan2
- ZNF461 | c.1416G>A p.M472I | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV64453309; called by muse, mutect2, varscan2
- ZNF513 | c.1072A>G p.K358E | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV52010377; called by muse, mutect2, varscan2
- ZNF521 | c.3442G>C p.E1148Q | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as COSV64129859, COSV64131756; called by muse, mutect2, varscan2
- ZNF662 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.401); catalogued as rs1183616393, COSV60243009; called by muse, mutect2, varscan2
- ZNF680 | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs1284900634, COSV59016863, COSV59018019; called by muse, mutect2, varscan2
- ZNF697 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs1286103085, COSV101360270; called by muse, mutect2, varscan2
- AP3B1 | c.2382del p.R795Efs*25 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- CELSR1 | c.3209_3210del p.Y1070Cfs*26 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- LDHB | c.832_835delinsTT p.V278Lfs*7 | Frame Shift Del (DEL) | VAF 32/80 reads (40%) | called by pindel, varscan2*
- MAGOH | c.268del p.I90Sfs*40 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- PIBF1 | c.682_685del p.E228Ifs*17 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | called by mutect2, pindel
- TNRC18 | c.7408dup p.T2470Nfs*9 | Frame Shift Ins (INS) | VAF 9/21 reads (43%) | called by mutect2, pindel, varscan2
- ABCC11 | c.4119C>A p.L1373= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as COSV62325781; called by muse, mutect2, varscan2
- ACAP2 | c.522G>A p.V174= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as COSV58755697; called by muse, mutect2, varscan2
- ACP1 | c.195G>A p.K65= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV55245452; called by muse, mutect2, varscan2
- ACSF3 | c.1656G>A p.L552= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1025781878, COSV100441516; called by muse, mutect2
- ALKBH6 | c.381C>T p.I127= (on ENST00000252984 / NM_001297701.2; = p.I155= on NM_032878.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as rs1411255517, COSV99431254; called by muse, mutect2
- ALS2CL | c.2541G>A p.T847= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs370602500; called by muse, mutect2, varscan2
- BORA | c.528A>G p.E176= (on ENST00000613797; = p.E101= on NM_024808.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/157 reads (6%) | catalogued as COSV64695861; called by muse, mutect2
- C6orf201 | c.22C>T p.L8= | Silent (SNP) | VAF 48/306 reads (16%) | catalogued as COSV60988917; called by muse, mutect2
- CA1 | c.417T>A p.A139= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV56280028; called by muse, mutect2, varscan2
- CD19 | c.855G>A p.L285= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs1378598991, COSV61189581; called by muse, mutect2, varscan2
- CEACAM5 | c.1833C>A p.L611= | Silent (SNP) | VAF 40/429 reads (9%) | catalogued as COSV55755018; called by muse, mutect2
- CERT1 | c.1590G>A p.Q530= (on ENST00000405807 / NM_001130105.1; = p.Q402= on NM_005713.3) | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV54655584; called by muse, mutect2, varscan2
- DAGLB | c.1332C>T p.L444= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs769189989, COSV51706834; called by muse, mutect2, varscan2
- DEAF1 | c.444G>C p.L148= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV58609255; called by muse, mutect2, varscan2
- DMBT1 | c.6060C>A p.S2020= (on ENST00000338354 / NM_001377530.1; = p.S1263= on NM_004406.3) | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV57560865; called by muse, mutect2
- DNAJC16 | c.609G>A p.E203= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV65449454; called by muse, mutect2, varscan2
- ERMP1 | c.1386C>T p.F462= | Silent (SNP) | VAF 95/207 reads (46%) | catalogued as rs768950275, COSV53039513; called by muse, mutect2, varscan2
- FLG | c.5646G>A p.G1882= | Silent (SNP) | VAF 50/366 reads (14%) | catalogued as rs1365087886, COSV64248710; called by muse, varscan2
- G3BP2 | c.282C>T p.V94= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as rs1387520420, COSV62977620; called by muse, mutect2, varscan2
- GBP3 | c.1578G>A p.V526= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV52520009; called by muse, mutect2, varscan2
- GTSE1 | c.1566G>A p.L522= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV71889744; called by muse, mutect2, varscan2
- INSYN1 | c.564C>T p.F188= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs1472422142, COSV65837929; called by muse, mutect2, varscan2
- IQGAP3 | c.4440G>A p.R1480= | Silent (SNP) | VAF 94/149 reads (63%) | catalogued as COSV63254527; called by muse, mutect2, varscan2
- KHNYN | c.861C>T p.L287= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV52159465, COSV52161266; called by muse, mutect2, varscan2
- KIAA1614 | c.1983G>A p.K661= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV62551784; called by muse, mutect2, varscan2
- KRTAP15-1 | c.159G>A p.E53= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV61878036; called by muse, mutect2, varscan2
- LAMA1 | c.4695G>A p.L1565= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV67544135; called by muse, mutect2, varscan2
- LONP1 | c.996C>T p.S332= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as rs752556297, COSV62263294; called by muse, mutect2, varscan2
- MKLN1 | c.1599C>T p.L533= | Silent (SNP) | VAF 70/194 reads (36%) | catalogued as COSV61762733; called by muse, mutect2, varscan2
- MMP24 | c.1875C>T p.F625= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV55773094; called by muse, mutect2, varscan2
- MORC3 | c.2769T>C p.D923= | Silent (SNP) | VAF 12/169 reads (7%) | catalogued as COSV68689253; called by muse, mutect2
- MT1A | c.21C>T p.C7= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as rs776240151, COSV51947260; called by muse, mutect2, varscan2
- MTTP | c.2370C>T p.I790= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV55509692; called by muse, mutect2, varscan2
- MUSK | c.1656C>T p.P552= | Silent (SNP) | VAF 34/178 reads (19%) | catalogued as COSV51896427; called by muse, mutect2, varscan2
- NAV2 | c.2892C>T p.L964= (on ENST00000396087 / NM_001244963.2; = p.L941= on NM_145117.5) | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV60665124; called by muse, mutect2, varscan2
- NECAP2 | c.36C>G p.V12= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs1418181625, COSV59188757, COSV59188773; called by muse, mutect2, varscan2
- NLRC3 | c.2646C>T p.I882= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs773196225, COSV57089373; called by muse, varscan2
- NTSR1 | c.759G>A p.S253= | Silent (SNP) | VAF 70/127 reads (55%) | catalogued as rs749682716, COSV65139565; called by muse, mutect2, varscan2
- NYAP2 | c.714C>T p.P238= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs759722204, COSV56016268; called by muse, mutect2, varscan2
- OAS2 | c.2133G>T p.L711= | Silent (SNP) | VAF 73/165 reads (44%) | catalogued as COSV60804463; called by muse, mutect2, varscan2
- OLFML1 | c.729G>A p.K243= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV55082190; called by mutect2, varscan2
- OR2T34 | c.159C>G p.L53= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV100170498; called by muse, mutect2, varscan2
- OXTR | c.630C>T p.I210= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs761354136, COSV57480907; called by muse, mutect2, varscan2
- PCDHGA12 | c.1374C>T p.S458= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs1468632362, COSV52754602; called by muse, mutect2, varscan2
- PDHA1 | c.960C>G p.L320= | Silent (SNP) | VAF 26/38 reads (68%) | catalogued as COSV58838190; called by muse, mutect2, varscan2
- POM121C | c.2577C>T p.F859= (on ENST00000607367; = p.F617= on NM_001099415.3) | Silent (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- PRELID3B | c.432G>A p.L144= | Silent (SNP) | VAF 48/100 reads (48%) | catalogued as COSV54813850; called by muse, mutect2, varscan2
- PUS7L | c.198T>C p.N66= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as rs1227074105, COSV100786585; called by muse, mutect2
- RAD54L | c.300G>C p.L100= | Silent (SNP) | VAF 72/117 reads (62%) | catalogued as COSV64336977; called by muse, mutect2, varscan2
- RELCH | c.2823T>G p.S941= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as rs1425069027, COSV56892077; called by muse, mutect2, varscan2
- RHCG | c.507C>T p.L169= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as COSV51518358; called by muse, mutect2, varscan2
- SIRT7 | c.669G>C p.R223= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs774005088, COSV58712601; called by muse, varscan2
- SLC31A1 | c.480C>A p.L160= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV65265071; called by muse, mutect2, varscan2
- SLITRK4 | c.936C>A p.I312= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV62026064; called by muse, mutect2, varscan2
- SPACA9 | c.408C>T p.G136= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs762539808; called by mutect2, varscan2
- SSX3 | c.12T>C p.D4= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV53646292; called by muse, mutect2
- TNPO3 | c.879G>A p.L293= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs1031002539, COSV55286696, COSV99602811; called by muse, mutect2, varscan2
- VPS33A | c.1485C>T p.L495= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1354266418, COSV57359273; called by muse, mutect2
- XYLB | c.789C>G p.V263= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV52915955; called by muse, mutect2, varscan2
- ZIC5 | c.1959C>T p.Y653= | Silent (SNP) | VAF 45/108 reads (42%) | catalogued as rs376832797; called by muse, mutect2, varscan2
- ZNF423 | c.717C>T p.F239= (on ENST00000563137 / NM_001379286.1; = p.F231= on NM_015069.4) | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV52194323; called by muse, mutect2, varscan2
- ZNF829 | c.372C>T p.F124= | Silent (SNP) | VAF 112/142 reads (79%) | catalogued as COSV66986940; called by muse, mutect2, varscan2
- ZUP1 | c.1656A>T p.A552= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV63946478, COSV63947116; called by muse, mutect2, varscan2
- ACTRT3 | chr3:169764653 G>A | 3'Flank (SNP) | VAF 9/19 reads (47%) | catalogued as CR015303; called by muse, mutect2, varscan2
- GH2 | c.456+28C>T | Intron (SNP) | VAF 17/100 reads (17%) | catalogued as rs778717942, COSV60427802; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.762C>T | RNA (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- MIR181A1 | n.9G>C | RNA (SNP) | VAF 41/102 reads (40%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 8/17 reads (47%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- TLK1 | c.406+1114C>T | Intron (SNP) | VAF 30/70 reads (43%) | catalogued as COSV62632916; called by muse, mutect2, varscan2
- UNC5D | c.104-4792G>T | Intron (SNP) | VAF 7/50 reads (14%) | catalogued as COSV54834655; called by muse, mutect2, varscan2
